Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AD3L, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AD3L-TTM1-A (Metastatic).

[page 1 of 12]
Patient: [REDACTED]
DOB: [REDACTED]
Age: [REDACTED] Sex: [REDACTED]

Accession #: [REDACTED]
Date of Surgery: [REDACTED]
Physician: [REDACTED]
Location: [REDACTED]
MRN: [REDACTED]
Acct #: [REDACTED]

+4334

SURGICAL PATHOLOGY

SPECIMEN SOURCE:

(1) DUODENAL POLYP, PORTIONS AND THROMBUS

CLINICAL INFORMATION:

Preoperative Diagnosis: Benign neoplasm of duodenum

Postoperative Diagnosis: Await pathology

Surgical Procedure: Flexible EGD

DIAGNOSIS

Duodenal polyp, portions and thrombus: Metastatic renal cell carcinoma

GROSS PATHOLOGY:

Specimen is received in formalin and labeled "portions of duodenal polyp and thrombus". There is an aggregate 1.6 x 1.2 x 0.5 cm of multiple irregular, partly rounded fragments of pink-tan tissue with adherent purple clot. The largest single fragment has the greatest dimension of 0.8 cm. These several largest fragments are sectioned, and the specimen is entirely submitted in one cassette. [REDACTED]

+4335

MICROSCOPIC PATHOLOGY:

The sections include portions of duodenum with a large collection of granulation tissue along with fibrin and inflammatory exudate on the surface of the polypoid mass. There are areas of entrapped clear cells with bland nuclei. The area of the entrapped clear cells is also highly vascular. This area is staining positive with renal cell carcinoma antigen, Vimentin, AE1/AE3, EMA, and CD34. Stains are performed on block 1A. Positive and negative stain controls are satisfactory (see Note).

Final Pathology Report

+4337

Page 1 of 2

[page 2 of 12]
Patient: [REDACTED]
DOB: [REDACTED]
Age: [REDACTED] Sex: [REDACTED]

Accession #:
Date of Surgery:
Physician:
Location:
MRN:
Acct #:

+4334

FDA AND CAP NOTE: These tests were developed and the performance characteristics determined by [REDACTED]. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 3 of 12]
PAGE: 1
+4348

RADIOLOGY
******* FINAL *******
REPORT

Result [REDACTED] Page 1 of 1		DATE-TIME OF REQUEST/REPORT/PRIORITY [REDACTED]		ORDER NO. [REDACTED]		ORDERING PHYSICIAN [REDACTED]	
ROOM NO. [REDACTED]	ACCOUNT NO. [REDACTED]	SEX/AGE [REDACTED]	BIRTHDATE [REDACTED]	MEDICAL REC NO. [REDACTED]	ADMISSION DATE [REDACTED]	TECH [REDACTED]	ADMITTING PHYSICIAN [REDACTED]
PATIENT NAME [REDACTED]					DATE PRINTED [REDACTED]	CPT4CODE [REDACTED]	

+4348

***** FINAL ***** PET-TUMOR, OTHER

EXAM: Whole-body PET CT scan.

HISTORY: Kidney cancer. Post nephrectomy 12 years ago. Metastasis the duodenum.

COMPARISON: None of this type..

PROCEDURE: The patient was injected with 19.49 millicuries of F-18 FDG and allowed to rest in a quiet room for approximately 1 hour. The patient was then placed on the scanning table and a whole body scan performed from the skull base through the level of the pubic symphysis in conjunction with a spiral CT scan from the skull base through the pubic symphysis utilized both for attenuation correction and also for the creation of a spatially registered CT examination for PET / CT fusion. The CT scan, PET scan and fused PET/CT scan were presented for evaluation in axial, sagittal and coronal planes. Additional images including a rotating maximum intensity projection image of the PET scan were provided as required. (The noncontrast CT images utilized for fusion with the PET images to create the PET / CT images are not of diagnostic quality and are not used to diagnose disease independently of the PET images.) The patient's blood glucose level was 111 milligrams per deciliter.

FINDINGS:

In the head and neck, the included portions of the orbits and paranasal sinuses demonstrate generally normal levels of activity. The nasopharynx, oropharynx and oral cavity demonstrate generally normal levels of activity. The larynx and vocal cords demonstrate generally normal activity. The salivary glands demonstrate generally normal levels of activity. The thyroid gland demonstrates generally normal levels of activity. No FDG avid lymph nodes are seen in the neck. Note is made of surgical clips adjacent to the left thyroid lobe and modest increased activity in the musculature in the neck and shoulders.

In the thorax, the lungs are generally well expanded with no evidence of significant infiltrate or consolidation or effusion. No FDG avid nodules are seen within the lung fields. No FDG avid lymph nodes are seen within the hila or mediastinum. The thoracic aorta is normal in caliber. There is modest atherosclerotic calcification of the aortic arch. There are calcified granulomatous nodes in the left hilum. The heart is normal in size. There is minimally increased physiologic uptake of FDG within the left ventricular myocardium..

In the abdomen and pelvis, the liver demonstrates a typical heterogeneous pattern of activity. The representative SUV max for the liver is 4.6. The spleen is normal in appearance. The stomach is

*** CONTINUED ***

[page 4 of 12]
Result (Rev. _____) Page 1 of 1		DATE-TIME of REQUEST/REPORT		PRIORITY	ORDER NO.	ORDERING PHYSICIAN
ROOM NO.	ACCOUNT NO.	SEX	AGE	BIRTHDATE	MEDICAL REC NO.	ADMISSION DATE TECH
PATIENT NAME					DATE PRINTED	CPT4 CODE

+4348

***** FINAL ***** PET-TUMOR, OTHER

physiologically distended with ingested material and demonstrates normal levels of activity. The pancreas is partially obscured. The body and tail appear unremarkable. At the juncture of the body and head there appears to be a large cyst of undetermined origin. There is a mass in the region of the head and duodenal C-loop with associated increased uptake of FDG with SUV max of 7.3. CT evaluation of this area with intravenous and oral contrast is recommended to more completely delineate the associated anatomy. There is increased activity in the left adrenal gland which appears normal in size and contour and demonstrates an SUV max of 6.8. The right adrenal gland cannot be differentiated and may be absent. The gallbladder is normally distended and contains no identifiable stones. The patient is post right nephrectomy. The left kidney appears normal and demonstrates normal physiologic levels of activity. The urinary bladder is normally distended. There are surgical staples along the anterior margin of the right psoas muscle which may be associated with prior node or ureter resection. Correlation with the patient's operative history is suggested in this regard. The abdominal aorta is normal in caliber. There is modest atheromatous calcification of the aorta. There is no evidence of ascites or pneumoperitoneum. Activity within the small bowel is generally within normal limits. The colon demonstrates a generally physiologic distribution of activity. There are curvilinear calcifications in the region of prostate gland. The gland does not appear abnormally enlarged.

The included portions of the skeleton demonstrate normal physiologic levels of activity. Incidental note is made of prior anterior cervical fusion.

IMPRESSION:

1. The PET CT examination demonstrates normal levels of activity in included portions of the head and neck.
2. The examination demonstrates normal levels of activity in the thorax.
3. The examination demonstrates evidence of right nephrectomy and possibly adrenalectomy. The left kidney appears normal. There is a normal activity in the liver and spleen. There is increased activity in the left adrenal gland.
4. There is an ill-defined mass in the region of the duodenal C-loop and pancreatic head with regions of abnormally increased activity with SUV max of approximately 7.3. There is also a cyst in the region of the juncture of the pancreatic head and body. The low resolution noncontrast CT examination accompanying the PET scan is

*** CONTINUED ***

[page 5 of 12]
+4348

PAGE: 3

RADIOLOGY
******* FINAL *******
REPORT

Result (R)		Page 1 of 1		DATE-TIME of REQUEST/REPORT PRIORITY		ORDER NO.		ORDERING PHYSICIAN	
ROOM NO.	ACCOUNT NO.	SEX	AGE	BIRTHDATE	MEDICAL REC NO.	ADMISSION DATE	TECH	ADMITTING PHYSICIAN	
PATIENT NAME						DATE PRINTED		CPT4CODE	
								+4348	

***** FINAL ***** PET-TUMOR, OTHER

insufficient to differentiate individual anatomic structures in this region. Further evaluation with an oral and intravenous contrast enhanced CT examination is suggested to provide better anatomic correlation.

5.The examination demonstrates normal levels of activity in included portions of the skeleton.

Original signature on file

[page 6 of 12]
Patient:

Age/Sex/DOB:
EMRN:
OMRN:
Home:
Work:

Results

Lab Accession #
Ordering Provider:
Performing Location:

Collected:
Resulted:
Verified By:
Auto Verify:

+4382
+4382

CT - Abdomen and Pelvis, with/without contrast -

Stage: Final

Test

Result

Units

Flag Reference Range

CT Abd \T\ Pelvis wwo cont

****FINAL REPORT****

The radiology attending physician has personally reviewed this study, and has reviewed and/or edited this written report and agrees with it.

ACC# Date Time Exam +4382

CT Abd \T\ Pelvis wwo cont

ACC# Date Time Exam +4382

CT Abd \T\ Pelvis wwo cont

EXAMINATION: CT of the abdomen and pelvis without and with contrast

HISTORY: Metastatic renal cell carcinoma

TECHNIQUE: CT of the abdomen and pelvis was obtained according to standard renal protocol after the uneventful administration of 121 mL of Optiray-350 Intravenous contrast.

FINDINGS:

[page 7 of 12]
Patient: [REDACTED]

EMRN: [REDACTED]

Test

Result

Units

Flag Reference Range

Comparison is made to a PET/CT from outside facility dated [REDACTED] +4348

Postsurgical changes are noted from prior right nephrectomy. There is an enhancing mass arising from the head of the pancreas or the pancreaticoduodenal groove, measuring approximately 6.9 x 6.2 cm. There are numerous smaller enhancing nodules seen in the pancreas. For example, a mass in the mid body at slice position -292 measures 3.4 x 2.5 cm and causes pancreatic duct obstruction. There is atrophy of the distal body and tail the pancreas. There is a cystic structure arising from the pancreas, likely related to ductal obstruction and pseudocyst formation, which measures approximately 5.5 x 5.8 cm at slice position -313.2.

Another mass invades the superior mesentery vein and extends into the main pulmonary vein, which has resulted in cavernous transformation. There are gallbladder and esophageal varices and omental collaterals present. There is no extension of mass into the inferior vena cava. The splenic vein is patent.

There is a mass just inferior to the tail of the pancreas, which is centrally necrotic and measures approximately 6.3 x 5.1 cm. It is likely retroperitoneal and located in the left pararenal fat.

Enhancing mass involves and encases the wall of the second portion of duodenum; however, there is no evidence of bowel obstruction.

There is a left adrenal mass, likely metastatic, measuring approximately 1.8 x 1.8 cm.

There are numerous parenchymal and intravascular bilateral pulmonary nodules. For example, there is an intravascular nodule seen at slice position -141.

There is a 5 mm hypoattenuating mass in the left kidney at slice position -351.2, which is too small to characterize but may represent a cyst. The spleen is normal. The visualized bowel is normal in course and caliber. Bone windows reveal no suspicious lytic or blastic lesions.

Though comparison is difficult due to lack of intravenous contrast, these findings are similar to those seen on the recent outside hospital PET/CT.

IMPRESSION:

1. Recurrent and widely metastatic renal cell carcinoma. Multiple pancreatic masses are seen including a large mass in the head of the pancreas or pancreaticoduodenal groove, with multiple foci of obstruction and pseudocyst formation. There is tumor seen in the left pararenal fat. Tumor mass is also seen in the superior mesenteric vein extending to the portal vein resulting in cavernous transformation.

2. Extensive metastatic disease in the lungs, including parenchymal and intravascular metastases.

[page 8 of 12]
Patient: [REDACTED]

EMRN: [REDACTED]

Test	Result	Units	Flag	Reference Range
-------------	---------------	--------------	-------------	------------------------

[REDACTED]				
------------	--	--	--	--

[page 9 of 12]
+4470

Result (R)		Page 1 of 1		DATE-TIME of REQUEST/REPORT		PRIORITY	ORDER NO.	ORDERING PHYSICIAN
ROOM NO.	ACCOUNT NO.	SEX	AGE	BIRTHDATE	MEDICAL REC NO.	ADMISSION DATE	TECH	ADMITTING PHYSICIAN
OUT-ONE								+4470
PATIENT NAME						DATE PRINTED	CPT4 CODE	

***** FINAL ***** CT CHEST W

Exam:

CT of the abdomen without contrast.

CT of the chest, abdomen and pelvis with IV contrast.

HISTORY: Prior renal carcinoma with nephrectomy. The.

Comparison: +4348

TECHNIQUE: Contiguous axial images at 5 mm intervals were obtained from the lung bases to the lower abdomen before administration of IV contrast. After the administration of IV contrast, contiguous axial images at 5 mm intervals were obtained from the lung apices to the pubic symphysis. Delayed images were obtained through the bladder. Coronal reformats were reviewed. Oral contrast was also given.

FINDINGS:

* Chest: The lungs are clear without consolidation or effusion. There is a calcified granuloma in the superior segment of the left lower lobe. In the left upper lobe, there is a 1.2 cm nodular density near the hilum. This is not definitely calcified on the study.

Abdomen: Patient is status post right nephrectomy. The right adrenal gland is not well seen. Extensive heterogeneous densities seen in the region of the head of the pancreas and portal vein. There appears to be a mass in the head of the pancreas measuring up to 5.7 x 5.8 cm. Adjacent cystic mass is seen measuring 6.5 x 4.6 cm which has appearance of a pseudocyst. The pancreatic duct is dilated measuring up to 10 mm. Multiple portal vein varicosities are seen. The portal vein appears enlarged with thrombus measuring up to 2.8 cm. The inferior vena cava in this area is difficult to identify. There is thickening of the wall of the second portion of the duodenum which may be due to inflammation or mass lesion. Near the tail of the pancreas, there is a 4.8 x 5.0 cm mass with low central density which has appearance of necrosis. This may be a pancreatic mass or necrotic lymph node.

The liver enhances uniformly. No masses or intrahepatic dilatation. The gallbladder is distended. There are prominent pericholecystic vessels. No definite masses are seen. No stones are seen. The spleen is unremarkable. There is a 1.5 cm mass in the left adrenal gland which demonstrates enhancement. The left kidney enhances uniformly. There are no masses, hydronephrosis or nephrolithiasis. There is no retroperitoneal adenopathy. Aorta is unremarkable.

The bowel is well opacified. There are no dilated loops of small bowel to suggest small bowel obstruction. Diverticulosis is seen without evidence of acute diverticulitis.

*** CONTINUED ***

[page 10 of 12]
RADIOLOGY
***** FINAL *****
REPORT

Result		Page 1 of 1		DATE-TIME of REQUEST/REPORT		PRIORITY	ORDER NO.	ORDERING PHYSICIAN	
ROOM NO.	ACCOUNT NO.	SEX	AGE	BIRTHDATE	MEDICAL REC NO.	ADMISSION DATE	TECH	ADMITTING PHYSICIAN	
OUT-ONE									
PATIENT NAME						DATE PRINTED		CPT4CODE	

+4470

***** FINAL ***** CT CHEST W

Pelvis: The bladder is not well distended otherwise appears normal. There is a trace amount of free fluid the pelvis. A large amount stool seen in the rectum.

Osseous structures: No acute fractures. No definite lytic or blastic lesions.

Impression:

1. Post right nephrectomy and adrenalectomy.
2. Extensive soft tissue mass in the right upper quadrant. There appears to be thrombosis of the portal vein with extensive varicosities. There is some flow in the portal veins which may be due to the varicosities or recanalization of the portal vein. There is also thrombosis of the superior mesenteric vein.
3. Heterogeneous and enhancing mass in the head the pancreas measuring up to 5.8 cm. There is a mass near the tail of the pancreas measuring up to 5 cm. This may be a pancreatic mass or metastatic disease/lymphadenopathy with necrosis.
4. Probable pseudocyst of the head of the pancreas. Pancreatic ductal dilatation.
5. Thickening of the wall of the duodenum which has appearance of neoplastic infiltration. The narrowing lumen is significant and may be obstructing at some point.
6. Enhancing mass in the left adrenal gland concerning for metastatic disease.
7. No acute pulmonary disease. Nodular density in left perihilar region is not definitely calcified and metastatic disease cannot be excluded. There are calcified granulomas and calcified lymph nodes.

Note: The portal vein thrombosis and shortness of breath thrombosis may be minimal to interventional radiology manipulation and treatment. Percutaneous biopsy of the mass may also be beneficial. Consider consultation clinically indicated.

Original signature on file

[page 11 of 12]
+5610

PAGE: 1

RADIOLOGY
***** FINAL *****
REPORT

Result of	Page 1 of 1	DATE-TIME OF REQUEST/REPORT	PRIORITY	ORDER NO.	ORDERING PHYSICIAN
ROOM NO.	ACCOUNT NO.	SEX/AGE	BIRTHDATE	MEDICAL REC NO.	ADMISSION DATE/TECH
OUT-ONE					ADMITTING PHYSICIAN
PATIENT NAME				DATE PRINTED	CPT4 CODE

+5610

***** FINAL ***** CT CHEST W

EXAM: CT scan of the chest, abdomen and pelvis with contrast

HISTORY: Cancer of the kidney.

TECHNIQUE: Imaging of the chest, abdomen and pelvis was performed following the intravenous administration of contrast. 5 mm thick axial images and coronal and sagittal reconstructions were provided for interpretation.

+5112

Comparison CT scan of the chest, abdomen and pelvis.

FINDINGS: The heart is normal size. No mediastinal masses are seen. There is stable appearance of a small nodular density seen in the subpleural location of the right lower lobe seen on axial image number 43. The findings measure 6 mm maximum. An additional nodular density is identified in the lateral left lung base along the costophrenic angle seen on axial image number 15. The lesion measures up to 7 mm AP and this may be slightly increased in size when compared to previous study. There is stable appearance of a nodular density seen in the left lower lobe seen on axial image number 41 measuring up to 9 mm transverse maximum. There is stable appearance of a larger tubular opacity seen in the right lower lobe seen on axial image number 38. The findings measure up to 2.2 cm AP. There is stable appearance of a nodular density seen in the left upper lobe seen on axial image #25 measuring up to 10 mm AP.

The patient has had right nephrectomy. There is a large mass lesion seen within the head of the pancreas. The findings measure 6.5 cm AP, 6.7 cm transverse. The findings are again noted to be associated with internal hypodense changes. There is a large adjacent cyst seen more anteriorly measuring approximately 7.4 cm transverse, 6.5 cm AP, and this is not significantly changed.

There is a large soft tissue mass lesion seen located medial to the superior pole of the left kidney seen on axial image #66. The lesion is thought to be arising from the left adrenal gland and measures up to 5.4 cm transverse, 4.9 cm AP, and this is not significantly changed. Multiple tortuous vessels are again seen in the region of the porta hepatis seen on axial image number 16.

The small and large bowel loops are normal caliber. The helical images obtained through the pelvis demonstrate a normal appearance of the rectum, urinary bladder. There is no free fluid seen within the pelvis. No retroperitoneal abnormalities are seen. No lytic or blastic lesions are seen within the osseous structures.

IMPRESSION:

1. A large necrotic mass lesion or metastatic lesion is again seen

*** CONTINUED ***

[page 12 of 12]
RADIOLOGY
***** FINAL *****
REPORT

PAGE: 2
+5610

Result		Page 1 of 1		DATE-TIME of REQUEST/REPORT		PRIORITY	ORDER NO.	ORDERING PHYSICIAN
ROOM NO.	ACCOUNT NO.	SEX	AGE	BIRTHDATE	MEDICAL REC NO.	ADMISSION DATE	TECH	ADMITTING PHYSICIAN
OUT-ONE								+5610
PATIENT NAME						DATE PRINTED	CPT4CODE	

***** FINAL ***** CT CHEST W

in the head of the pancreas and the findings are not significantly changed when compared to previous study.

2. Stable appearance of an adjacent cystic structure seen along the body of the pancreas and the findings may represent a large pseudocyst.
3. Stable appearance of a large left adrenal mass lesion.
4. There has been previous right nephrectomy and resection of the right adrenal gland.
5. Multiple pulmonary nodules are seen as described above. The majority of the nodules appear to be unchanged. There may be slight increase in size of the nodule in the lateral left lung base.
6. Tortuous vessels are identified in the region of the porta hepatis and the findings may represent hypervascularity associated with the large mass lesion seen within the head of the pancreas.

Original signature on file

Source: NCI Genomic Data Commons file a61efe09-47c0-4589-bf7a-adbd03283418 (ER0291 ER-AD3L Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).